Somatic mutation profile of tumor specimen TCGA-13-0897-01A (aliquot TCGA-13-0897-01A-01W-0420-08) from TCGA case TCGA-13-0897, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 54.5 years (19,894 days).
Specimen TCGA-13-0897-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5224cd1b-7b50-42ca-b787-fd73268c1276.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0897-10A (Blood Derived Normal), aliquot TCGA-13-0897-10A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/035aeea9-9a13-4b41-9af6-29a4fa477765

The open-access MAF lists 60 somatic variants for this specimen: 49 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 35, Silent 11, Frame Shift Del 5, Nonsense Mutation 4, Splice Site 2, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 7/21 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913381, CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; ClinVar: likely pathogenic; called by muse, mutect2
- ABHD6 | c.1001A>G p.K334R | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV55909404; called by muse, mutect2, varscan2
- ADGRV1 | c.1722C>G p.I574M | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV67990057; called by muse, mutect2, varscan2
- ASH2L | c.290C>G p.T97S | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV51700363; called by muse, mutect2, varscan2
- BAG3 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.599); catalogued as rs1454148171, COSV64842287; called by muse, mutect2, varscan2
- BRD4 | c.374G>A p.C125Y | Missense Mutation (SNP) | VAF 95/267 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54590016; called by muse, mutect2, varscan2
- CAMSAP1 | c.3204A>C p.K1068N | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.632); catalogued as COSV100409563; called by muse, mutect2, varscan2
- COL16A1 | c.2610+1G>A p.X870_splice | Splice Site (SNP) | VAF 25/73 reads (34%) | catalogued as COSV54710375; called by muse, mutect2, varscan2
- DTX3L | c.1156A>C p.K386Q | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.307); catalogued as COSV56144960; called by muse, mutect2, varscan2
- FAM135B | c.2674A>G p.R892G | Missense Mutation (SNP) | VAF 98/834 reads (12%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV52739054; called by muse, mutect2, varscan2
- FGD6 | c.4170G>C p.E1390D | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV59692623; called by muse, mutect2, varscan2
- GABRA1 | c.856+2T>A p.X286_splice | Splice Site (SNP) | VAF 200/329 reads (61%) | catalogued as COSV50111096; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 408/1002 reads (41%) | catalogued as rs746342179; called by muse, mutect2, varscan2
- ITK | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 129/551 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.451); catalogued as COSV70060980, COSV70063711; called by muse, mutect2, varscan2
- KIF15 | c.2706G>C p.L902F | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58162853; called by muse, mutect2, varscan2
- LURAP1 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.628); catalogued as COSV64338360; called by muse, mutect2, varscan2
- MAGEH1 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61678912; called by muse, mutect2, varscan2
- MFAP3L | c.79_102delinsTAACTA p.T27_S34delins* | Nonsense Mutation (DEL) | VAF 42/145 reads (29%) | catalogued as COSV64372502; called by pindel, varscan2*
- MYH11 | c.1568A>G p.E523G | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV100257669; called by muse, mutect2, varscan2
- MYH14 | c.5430G>T p.Q1810H | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV51824234, COSV51824621; called by muse, mutect2, varscan2
- NCOA6 | c.5408C>A p.S1803Y | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV62865650; called by muse, mutect2, varscan2
- NDUFS1 | c.1313T>G p.L438R | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51911494; called by muse, mutect2, varscan2
- NISCH | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as rs745490517, COSV61900384; called by muse, mutect2, varscan2
- NLGN3 | c.1506C>G p.Y502* (on ENST00000358741 / NM_181303.2; = p.Y482* on NM_018977.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 94/259 reads (36%) | catalogued as COSV62444415; called by muse, mutect2, varscan2
- NOX4 | c.150G>T p.L50F | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV54458138, COSV54458661; called by muse, mutect2, varscan2
- NT5DC3 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 238/589 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368049739, COSV101231049; called by muse, mutect2, varscan2
- ODAM | c.460T>G p.W154G | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); catalogued as COSV68572520, COSV68573154; called by muse, mutect2, varscan2
- OR2L8 | c.779G>C p.R260P | Missense Mutation (SNP) | VAF 105/346 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs572027464, COSV61727514, COSV61727605; called by muse, mutect2, varscan2
- OR5AS1 | c.794G>C p.S265T | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV100546228, COSV57982454; called by muse, mutect2, varscan2
- PALD1 | c.575T>A p.L192H | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54976258, COSV99698372; called by muse, varscan2
- RNF130 | c.819G>C p.Q273H | Missense Mutation (SNP) | VAF 62/335 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV56151823; called by muse, mutect2, varscan2
- RNF169 | c.1216A>G p.I406V | Missense Mutation (SNP) | VAF 93/340 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.56); catalogued as COSV55133996; called by muse, mutect2, varscan2
- RPL32 | c.277A>T p.K93* | Nonsense Mutation (SNP) | VAF 56/189 reads (30%) | catalogued as COSV55992051; called by muse, mutect2, varscan2
- RSPO2 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 195/587 reads (33%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.999); catalogued as COSV52649372; called by muse, mutect2, varscan2
- SLC17A6 | c.1195C>A p.L399M | Missense Mutation (SNP) | VAF 99/282 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV54138711, COSV54141154; called by muse, mutect2, varscan2
- SLC18B1 | c.754G>C p.G252R | Missense Mutation (SNP) | VAF 108/166 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51595357; called by muse, mutect2, varscan2
- SLC38A2 | c.1380G>C p.K460N | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV99873724; called by muse, mutect2
- SLCO5A1 | c.1031T>C p.I344T | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs750358609, COSV52663435; called by muse, mutect2, varscan2
- SLIT3 | c.1138T>A p.S380T | Missense Mutation (SNP) | VAF 74/284 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV60621090; called by muse, mutect2, varscan2
- TAS2R43 | c.856C>G p.L286V | Missense Mutation (SNP) | VAF 267/392 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV67858931; called by muse, varscan2
- TP53 | c.848_849insT p.T284Hfs*22 | Frame Shift Ins (INS) | VAF 127/267 reads (48%) | catalogued as COSV99367543; called by pindel, varscan2
- USP19 | c.1145dup p.L383Pfs*47 | Frame Shift Ins (INS) | VAF 8/41 reads (20%) | catalogued as rs775252063; called by mutect2, varscan2
- ZNF770 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.573); catalogued as COSV62544598; called by muse, mutect2, varscan2
- BCLAF1 | c.691_739del p.P231Cfs*91 | Frame Shift Del (DEL) | VAF 22/233 reads (9%) | called by mutect2, pindel
- CIC | c.3020_3032del p.V1007Afs*28 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- DMRT1 | c.484_511del p.C162Pfs*83 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | called by mutect2, pindel
- MCF2L2 | c.2391_2400del p.K797Nfs*12 | Frame Shift Del (DEL) | VAF 448/1152 reads (39%) | called by mutect2, pindel, varscan2
- MGA | c.6882del p.D2295Tfs*40 (on ENST00000219905 / NM_001164273.1; = p.D2086Tfs*40 on NM_001080541.2) | Frame Shift Del (DEL) | VAF 106/238 reads (45%) | called by mutect2, pindel, varscan2
- OR5AP2 | c.326_352del p.F109_E117del | In Frame Del (DEL) | VAF 32/114 reads (28%) | called by mutect2, pindel
- ATRIP | c.1560A>G p.G520= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV56497516; called by muse, mutect2, varscan2
- CHSY3 | c.1506G>A p.V502= | Silent (SNP) | VAF 6/107 reads (6%) | catalogued as COSV100518478; called by muse, mutect2
- CROCC | c.5238G>A p.R1746= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV65013538; called by muse, mutect2, varscan2
- CYP2F1 | c.666C>T p.S222= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as rs1377639448, COSV58528248; called by muse, mutect2, varscan2
- FAF1 | c.1668C>G p.S556= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as COSV65641096, COSV65642998; called by muse, mutect2, varscan2
- KIRREL2 | c.705A>G p.P235= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV52878242; called by muse, mutect2, varscan2
- OR5B2 | c.690G>A p.K230= | Silent (SNP) | VAF 95/238 reads (40%) | catalogued as COSV56909027; called by muse, mutect2, varscan2
- PGM1 | c.1008C>T p.P336= | Silent (SNP) | VAF 143/408 reads (35%) | catalogued as rs930181526, COSV64301000; called by muse, mutect2, varscan2
- PPP1R15B | c.198G>T p.L66= | Silent (SNP) | VAF 34/130 reads (26%) | catalogued as rs773326374, COSV65816119; called by muse, mutect2, varscan2
- RNF144A | c.13A>C p.R5= | Silent (SNP) | VAF 56/162 reads (35%) | catalogued as COSV57983819; called by muse, mutect2, varscan2
- SLC27A3 | c.1629C>A p.R543= (on ENST00000271857; = p.R415= on NM_024330.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/169 reads (27%) | catalogued as COSV55164665; called by muse, mutect2, varscan2
